Somatic mutation profile of tumor specimen TCGA-38-4627-01A (aliquot TCGA-38-4627-01A-01D-1553-08) from TCGA case TCGA-38-4627, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.4 years (23,510 days).
Specimen TCGA-38-4627-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca88b9f7-4be5-4972-9635-7e1e0daffd87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-4627-11A (Solid Tissue Normal), aliquot TCGA-38-4627-11A-01D-1553-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b883874a-5435-4fa9-af0d-42bf7056184c

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 20, Silent 4, Nonsense Mutation 3, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 36/240 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 18/134 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ALX1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV57494311; called by muse, mutect2, varscan2
- BCAS3 | c.1088-1G>T p.X363_splice | Splice Site (SNP) | VAF 28/310 reads (9%) | catalogued as COSV66782779; called by muse, mutect2
- BPIFC | c.683T>A p.L228Q | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV55916146; called by muse, mutect2
- CD34 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs1198314387, COSV60415316; called by muse, varscan2
- CDC23 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 20/136 reads (15%) | catalogued as COSV67510703; called by muse, mutect2, varscan2
- CDKAL1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs866091749, COSV51191899; called by muse, mutect2
- CHD9 | c.5360G>A p.R1787H | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs376635463, COSV54618268; called by muse, mutect2, varscan2
- DCAF4L2 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); catalogued as rs1222870245, COSV60482942, COSV60484032; called by muse, mutect2
- DMD | c.8779A>T p.R2927* | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | catalogued as COSV58955801; called by muse, mutect2
- HIRA | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760600000, COSV54280172; called by muse, mutect2, varscan2
- ITGAE | c.2651A>T p.Q884L | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV54000169; called by muse, mutect2, varscan2
- KLHL1 | c.1695C>A p.S565R | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64785112; called by muse, mutect2
- OR4K17 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs780993428, COSV59648742, COSV59649214; called by muse, mutect2, varscan2
- PCDH1 | c.3650C>T p.S1217L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs772924830, COSV54619750; called by muse, mutect2, varscan2
- PHF1 | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65703436; called by muse, mutect2
- PMS1 | c.2703C>G p.I901M | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV59715085; called by muse, mutect2
- RASA2 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs778607316, COSV53946715; called by muse, mutect2
- SLC17A1 | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV55082519; called by muse, mutect2, varscan2
- SLC9A9 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 17/170 reads (10%) | catalogued as COSV57246223; called by muse, mutect2, varscan2
- TMEM106B | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV67544772; called by muse, mutect2
- ZNF425 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs747368889, COSV65202763; called by muse, mutect2, varscan2
- MYH3 | c.2978del p.L993* | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, varscan2
- POLR2A | c.5105C>T p.T1702I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- CSMD2 | c.6396C>T p.G2132= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as rs1381129756, COSV53966693; called by muse, mutect2
- MXRA5 | c.6015C>T p.H2005= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs758500843, COSV54235580; called by muse, mutect2, varscan2
- OR5D14 | c.576T>A p.S192= | Silent (SNP) | VAF 36/454 reads (8%) | catalogued as COSV100161998; called by muse, mutect2
- TTN | c.65121C>T p.A21707= (on ENST00000591111; = p.A14283= on NM_003319.4) | Silent (SNP) | VAF 16/185 reads (9%) | catalogued as rs771534964, COSV60367232; ClinVar: uncertain significance; called by muse, mutect2
